TCGA case TCGA-K1-A42X — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9bdc3867-2115-4351-af5f-a52a2c20ae5d

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (3)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 62.1 years (22,680 days); Year of diagnosis: 2003; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Uterus.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 7; Tumor length measurement: 7; Tumor width measurement: 7.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 5.5; Tumor length measurement: 5.5; Tumor width measurement: 5.5.
   Pathology details: Measurement type: Pathologic; Tumor burden: 7.
   Pathology details: Measurement type: Radiologic; Tumor burden: 5.5.
2. Recurrence of diagnosis 1 (Leiomyosarcoma, NOS). Age at diagnosis: 67.7 years (24,716 days); Days to diagnosis: 2,036 days (5.6 years); Prior treatment: Yes.
3. Recurrence of diagnosis 1 (Leiomyosarcoma, NOS), site: Abdomen, NOS. Age at diagnosis: 67.7 years (24,744 days); Days to diagnosis: 2,064 days (5.7 years); Prior treatment: Yes.
   Pathology details: Additional pathology findings: Well Differentiated.

Follow-up (4 entries)
- Day 2,036 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 2,036 days (5.6 years).
- Day 2,064 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Abdomen, NOS; Days to recurrence: 2,064 days (5.7 years).
- Days to follow up: 3,289 days (9.0 years); Disease response: Tumor Free.
- Days to follow up: 3,765 days (10.3 years); Disease response: With Tumor.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-K1-A42X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 390 mg.
  Slide TCGA-K1-A42X-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-K1-A42X-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-K1-A42X-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 320 mg.
  Slide TCGA-K1-A42X-02A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-K1-A42X-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 310 mg.
  Slide TCGA-K1-A42X-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Tumor burden pathologic: 7.0.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gynecological - Uterus.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic length: 7.0; Lesion pathologic width: 7.0; Lesion pathologic depth: 7.0.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 2134; Days from index date to pharmaceutical treatment ended: 2293; Pharmaceutical therapy drug name: Doxil; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 3256; Days from index date to pharmaceutical treatment ended: 3417; Pharmaceutical therapy drug name: Gemzar; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,765 days; disease-specific survival: no event (censored), 3,765 days; disease-free interval: event (new tumor event after initially disease-free), 2,036 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,036 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-K1-A42X-01A-11D-A24M-01): tumor purity 0.97, ploidy 1.91, whole-genome doublings 0.
Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-K1-A42X-02A-11D-A24M-01): tumor purity 0.96, ploidy 1.91, whole-genome doublings 0.
